Somatic mutation profile of tumor specimen TCGA-KU-A6H8-01A (aliquot TCGA-KU-A6H8-01A-21D-A34J-08) from TCGA case TCGA-KU-A6H8, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 41.2 years (15,066 days).
Specimen TCGA-KU-A6H8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2450ff26-b4f7-4ce1-a0c5-bfd35b5ad011.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KU-A6H8-10A (Blood Derived Normal), aliquot TCGA-KU-A6H8-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/449dbea2-5503-4673-a02c-fde959bf3283

The open-access MAF lists 25 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 18, Silent 4, Nonsense Mutation 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC024598.1 | c.1004A>T p.H335L | Missense Mutation (SNP) | VAF 38/295 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV101237869; called by muse, mutect2, varscan2
- ADGRA3 | c.3190G>T p.G1064* | Nonsense Mutation (SNP) | VAF 12/60 reads (20%) | catalogued as COSV99293197; called by muse, mutect2, varscan2
- ATP13A5 | c.1583C>T p.A528V | Missense Mutation (SNP) | VAF 19/158 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.366); catalogued as rs757220508, COSV100665036, COSV60868736; called by muse, mutect2
- ATP8B1 | c.505A>G p.M169V | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as rs1461534052, COSV99377186; called by muse, mutect2, varscan2
- CAMSAP3 | c.251A>G p.Y84C | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99350463; called by muse, mutect2, varscan2
- CD1E | c.1109C>T p.S370L | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV63770168; called by muse, mutect2
- CHD2 | c.2573C>G p.S858C | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101245103; called by muse, mutect2, varscan2
- FSTL5 | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.538); catalogued as COSV100054463; called by muse, mutect2
- IGSF11 | c.607C>T p.R203W (on ENST00000393775 / NM_001015887.3; = p.R202W on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs779100034, COSV61164767; called by muse, mutect2, varscan2
- KL | c.2777G>T p.G926V | Missense Mutation (SNP) | VAF 27/178 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777651747, COSV101199073; called by muse, mutect2, varscan2
- MET | c.2067C>A p.H689Q | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.259); catalogued as rs1318989606, COSV59260220; called by muse, mutect2, varscan2
- NAV3 | c.7079C>T p.S2360L (on ENST00000397909 / NM_001024383.2; = p.S2338L on NM_014903.6) | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as rs866775667, COSV57107942, COSV99889758; called by muse, mutect2, varscan2
- PDXDC1 | c.842A>G p.Y281C | Missense Mutation (SNP) | VAF 41/633 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.962); catalogued as COSV100363088; called by muse, mutect2
- SLC16A4 | c.68T>C p.I23T | Missense Mutation (SNP) | VAF 29/187 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV100872935; called by muse, mutect2, varscan2
- SPATA20 | c.1441C>T p.L481F (on ENST00000356488 / NM_001258372.1; = p.L497F on NM_022827.4) | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as COSV99135856; called by muse, mutect2
- SPEN | c.4452C>A p.D1484E | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.87); PolyPhen benign (0.056); catalogued as COSV101005151; called by muse, mutect2, varscan2
- STXBP4 | c.1306-2A>T p.X436_splice | Splice Site (SNP) | VAF 4/78 reads (5%) | catalogued as COSV100894668; called by muse, mutect2
- TTN | c.57611C>T p.T19204M (on ENST00000591111; = p.T11780M on NM_003319.4) | Missense Mutation (SNP) | VAF 15/125 reads (12%) | PolyPhen probably damaging (0.999); catalogued as rs727505316, COSV100607660; ClinVar: benign / likely benign / uncertain significance; called by muse, mutect2, varscan2
- WDR83 | c.450T>A p.D150E | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.05); catalogued as COSV99269587; called by muse, mutect2, varscan2
- WNK3 | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs781802911, COSV63614287; called by muse, mutect2, varscan2
- TFCP2 | c.524del p.F175Sfs*24 | Frame Shift Del (DEL) | VAF 30/307 reads (10%) | called by mutect2, pindel, varscan2
- COL13A1 | c.1545C>A p.G515= (on ENST00000398978 / NM_001130103.2; = p.G458= on NM_080798.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV100637433; called by muse, mutect2, varscan2
- DSPP | c.1236C>T p.G412= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as rs761078802, COSV99217149; called by muse, mutect2, varscan2
- HDAC5 | c.3195C>T p.A1065= | Silent (SNP) | VAF 33/316 reads (10%) | catalogued as rs200613631, COSV52241973; called by muse, mutect2, varscan2
- SAG | c.813A>G p.K271= | Silent (SNP) | VAF 18/124 reads (15%) | catalogued as COSV101300662; called by muse, mutect2, varscan2
